Gene-level copy-number profile of tumor specimen TCGA-HU-A4GT-01A from TCGA case TCGA-HU-A4GT, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 71.8 years (26,231 days).
Specimen TCGA-HU-A4GT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.9db1d462-9edc-4cd1-8720-a4bea2095ff9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4GT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a11fe482-0951-49e9-b4d3-b1818e8479d7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 68; copy number 2: 50,004; copy number 3: 8,639; copy number 4: 783; copy number 5: 323; copy number 6: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4GT-01A-21D-A253-01): tumor purity 0.78, ploidy 2.22, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 326 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:75,407,914–96,611,790, 311 genes, copy number 5–6 (broad region; genes not listed).
- chr13:72,782,133–73,995,056, 15 genes, copy number 5 (within-gene range 3–5): PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1.

Autosomal genes at a single copy (total copy number 1): 68. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
